Somatic mutation profile of tumor specimen 0DSI8I from CCDI case PBCIFC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 17.9 years (6,520 days).
Specimen 0DSI8I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8869e6e-32c0-47d0-928f-ca28ed14d0b3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSI8A (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/72f22b35-1852-48fa-8943-367b26535111

The open-access MAF lists 45 somatic variants for this specimen: 29 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Nonsense Mutation 2, Intron 2, 5'UTR 1, 3'UTR 1, 5'Flank 1, In Frame Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 255/518 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- TP53 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 251/377 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs193920774, CM1414506, COSV52664019, COSV52666760, COSV53585299; ClinVar: pathogenic / likely pathogenic / uncertain significance / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CCDC190 | c.271C>T p.Q91* | Nonsense Mutation (SNP) | VAF 50/362 reads (14%) | catalogued as COSV63363058; called by muse, mutect2, varscan2
- FRMPD3 | c.3752A>G p.N1251S | Missense Mutation (SNP) | VAF 152/354 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs1159358767; called by muse, mutect2, varscan2
- GSDMA | c.151G>C p.A51P | Missense Mutation (SNP) | VAF 50/578 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1350873269; called by muse, mutect2
- INSR | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 89/696 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0.021); catalogued as rs773115239, COSV57164109; called by muse, mutect2, varscan2
- KCNS3 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 25/704 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV58406903; called by muse, mutect2
- KLK8 | c.71-6C>A | Splice Region (SNP) | VAF 75/369 reads (20%) | catalogued as COSV51593466; called by muse, mutect2, varscan2
- LRRC7 | c.1105G>A p.E369K (on ENST00000651989 / NM_001370785.2; = p.E336K on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/621 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as COSV50460086; called by muse, mutect2
- OBSCN | c.3584C>T p.T1195I | Missense Mutation (SNP) | VAF 252/466 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.716); catalogued as rs180718201; called by muse, mutect2, varscan2
- TBC1D2B | c.1766A>G p.H589R | Missense Mutation (SNP) | VAF 16/580 reads (3%) | SIFT tolerated (0.21); PolyPhen benign (0.236); catalogued as rs1160808781; called by muse, mutect2
- ABHD14A-ACY1 | c.1151G>A p.W384* | Nonsense Mutation (SNP) | VAF 44/425 reads (10%) | called by muse, mutect2, varscan2
- ANKLE2 | c.1109C>T p.T370I | Missense Mutation (SNP) | VAF 132/478 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ATRX | c.2735_2739dup p.A914Sfs*58 | Frame Shift Ins (INS) | VAF 99/240 reads (41%) | called by mutect2, pindel, varscan2
- CLTC | c.1270C>A p.Q424K | Missense Mutation (SNP) | VAF 72/801 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2
- CYP7B1 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 82/241 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- EDNRB | c.188T>C p.V63A | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- FUT3 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 176/526 reads (33%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); called by muse, varscan2
- GALR1 | c.472T>A p.C158S | Missense Mutation (SNP) | VAF 26/380 reads (7%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2
- LRIF1 | c.2191G>C p.V731L | Missense Mutation (SNP) | VAF 81/878 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2
- NEURL1 | c.1248_1277del p.A417_A426del | In Frame Del (DEL) | VAF 64/447 reads (14%) | called by mutect2, pindel
- OR10K1 | c.772A>T p.I258F | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- OR12D1 | c.589G>A p.G197R | Missense Mutation (SNP) | VAF 102/400 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PDZD2 | c.6164C>T p.P2055L | Missense Mutation (SNP) | VAF 296/602 reads (49%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLA2R1 | c.272G>C p.G91A | Missense Mutation (SNP) | VAF 61/489 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PRMT5 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPO | c.1634G>T p.R545I | Missense Mutation (SNP) | VAF 64/555 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- UHRF1 | c.1370C>T p.A457V (on ENST00000612630 / NM_001290050.1; = p.A470V on NM_013282.4) | Missense Mutation (SNP) | VAF 109/350 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ZNF554 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 61/314 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- ACACA | c.2256C>G p.L752= | Silent (SNP) | VAF 43/853 reads (5%) | catalogued as rs993085326; called by muse, mutect2
- ADRB2 | c.1209G>C p.G403= | Silent (SNP) | VAF 107/501 reads (21%) | called by muse, mutect2, varscan2
- C10orf71 | c.1371G>A p.L457= | Silent (SNP) | VAF 34/609 reads (6%) | called by muse, mutect2
- C2 | c.705G>A p.Q235= | Silent (SNP) | VAF 42/622 reads (7%) | called by muse, mutect2
- FHAD1 | c.141G>A p.A47= | Silent (SNP) | VAF 240/694 reads (35%) | catalogued as rs772727638; called by muse, mutect2, varscan2
- FSCB | c.558G>A p.S186= | Silent (SNP) | VAF 127/355 reads (36%) | catalogued as rs1175577064, COSV100468910, COSV61219859; called by muse, mutect2, varscan2
- GIPC3 | c.399C>T p.Y133= | Silent (SNP) | VAF 97/353 reads (27%) | catalogued as rs1010472144, COSV59260508; called by muse, mutect2, varscan2
- NFU1 | c.123A>G p.V41= (on ENST00000410022 / NM_001002755.4; = p.V17= on NM_015700.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 170/551 reads (31%) | catalogued as rs1392681049; called by muse, mutect2, varscan2
- PRDM15 | c.357C>T p.I119= | Silent (SNP) | VAF 69/401 reads (17%) | catalogued as rs1392027228, COSV54152344; called by muse, mutect2, varscan2
- TPO | c.1428C>T p.T476= | Silent (SNP) | VAF 19/512 reads (4%) | catalogued as COSV100222435; called by muse, mutect2
- ZNF554 | c.39C>T p.L13= | Silent (SNP) | VAF 58/315 reads (18%) | catalogued as rs1476108918; called by muse, mutect2, varscan2
- ALG5 | c.774-9C>T | Intron (SNP) | VAF 32/184 reads (17%) | catalogued as rs755845479; called by muse, mutect2, varscan2
- ATP5F1C | chr10:7788165 G>C | 5'Flank (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- GCM2 | c.-18C>T | 5'UTR (SNP) | VAF 35/204 reads (17%) | called by muse, mutect2, varscan2
- KHDRBS2 | c.*83G>A | 3'UTR (SNP) | VAF 6/61 reads (10%) | catalogued as rs1263917365; called by muse, mutect2
- KIF19 | c.1048-73G>T | Intron (SNP) | VAF 19/152 reads (13%) | called by muse, mutect2, varscan2
